Somatic mutation profile of tumor specimen C3N-03025-01 (aliquot CPT0225840006) from CPTAC case C3N-03025, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.2 years (28,566 days).
Specimen C3N-03025-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49b2b4aa-523f-4344-a178-bb653f7d4a6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03025-31 (Blood Derived Normal), aliquot CPT0225860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb12f3bd-a4bf-492d-92cd-223e59ddbb1b

The open-access MAF lists 95 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 18, Intron 6, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 3, RNA 2, In Frame Ins 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEPDC5 | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 91/183 reads (50%) | catalogued as rs1057519107; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 217/274 reads (79%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.1282-1G>A p.X428_splice (on ENST00000219054; = p.X349_splice on NM_001308169.2) | Splice Site (SNP) | VAF 41/83 reads (49%) | catalogued as COSV99524820; called by muse, mutect2, varscan2
- CCDC77 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs1193468671; called by muse, mutect2, varscan2
- CCL19 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs766142214; called by muse, mutect2, varscan2
- CDYL2 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as rs772092026, COSV73647784; called by muse, mutect2, varscan2
- CLEC4M | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376066614; called by muse, mutect2, varscan2
- CNGA1 | c.1208G>T p.R403I | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100652192; called by muse, mutect2, varscan2
- COL6A2 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 133/364 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56007190; called by muse, mutect2, varscan2
- CTNNA2 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 15/304 reads (5%) | catalogued as rs1215410582, COSV63589936, COSV63602878; called by muse, mutect2
- DDX4 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.978); catalogued as rs767407667; called by muse, mutect2, varscan2
- FRY | c.6940C>T p.R2314* | Nonsense Mutation (SNP) | VAF 87/225 reads (39%) | catalogued as COSV66583342; called by muse, mutect2, varscan2
- GRB10 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 103/453 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs772708204; called by muse, mutect2, varscan2
- IGF1R | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 424/612 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51354979; called by muse, mutect2, varscan2
- IKZF3 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs748446589, COSV53099754; called by muse, mutect2
- KCNAB1 | c.418G>A p.E140K (on ENST00000490337 / NM_172160.3; = p.E129K on NM_003471.3) | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919946760, COSV56740913; called by muse, mutect2, varscan2
- MRGPRD | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs772771135; called by muse, mutect2, varscan2
- MXRA5 | c.6356G>A p.R2119H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as rs749329546, COSV54230521; called by muse, mutect2, varscan2
- PANX2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 107/127 reads (84%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.516); catalogued as rs930213427; called by muse, mutect2, varscan2
- PDE1C | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.732); catalogued as rs148019533; called by muse, mutect2
- PIP | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs142425119; called by muse, mutect2, varscan2
- RBBP6 | c.4426_4429del p.D1476Mfs*18 | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | catalogued as rs1347954617; called by mutect2, pindel, varscan2
- RGPD4 | c.5255C>T p.A1752V | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs745348841, COSV61747975; called by muse, mutect2, varscan2
- ROPN1L | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200043905; called by muse, mutect2, varscan2
- SCN7A | c.2776A>G p.T926A | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV69274487; called by muse, mutect2, varscan2
- SLAMF1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as rs372403738; called by muse, mutect2, varscan2
- SLC38A4 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as rs1311032019, COSV56969984; called by muse, mutect2, varscan2
- SLC52A3 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 200/459 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs145498634, COSV54079007; called by muse, mutect2, varscan2
- TLR3 | c.1513C>G p.L505V | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99710874; called by muse, mutect2
- TMEM151A | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs895282819, COSV59174853; called by muse, mutect2, varscan2
- VDR | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs770566299; called by muse, mutect2, varscan2
- ZNF585B | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 125/244 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1405908614, COSV57214773; called by muse, mutect2, varscan2
- ACSM2A | c.1282-2A>T p.X428_splice (on ENST00000219054; = p.X349_splice on NM_001308169.2) | Splice Site (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2
- ADCYAP1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTL | c.949T>A p.S317T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, varscan2
- ATP6V1H | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CADM3 | c.139G>C p.V47L (on ENST00000368125 / NM_001127173.3; = p.V81L on NM_021189.5) | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- CCR3 | c.10T>G p.S4A | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.057); called by muse, varscan2
- CLPX | c.440_441del p.I147Kfs*4 | Frame Shift Del (DEL) | VAF 49/142 reads (35%) | called by mutect2, pindel, varscan2
- CTDSP2 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 109/722 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DHX38 | c.2474A>T p.Y825F | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- IGKV1D-42 | c.160A>C p.N54H | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IGSF22 | c.2372G>T p.S791I (on ENST00000319338; = p.S892I on NM_173588.4) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IQSEC3 | c.3364A>C p.T1122P | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- ITGA7 | c.525G>C p.E175D | Missense Mutation (SNP) | VAF 158/460 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPO | c.100A>T p.I34F | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MALRD1 | c.3851A>G p.D1284G | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAP1A | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- MAPKAPK2 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MFAP3L | c.302A>T p.K101I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- MST1R | c.2739G>C p.M913I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFIX | c.1441_1442del p.V481Qfs*32 (on ENST00000592199 / NM_001365902.3; = p.L431Ffs*23 on NM_002501.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 148/433 reads (34%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.956_961dup p.Y319_N320dup | In Frame Ins (INS) | VAF 161/485 reads (33%) | called by mutect2, varscan2
- NTN4 | c.800A>C p.H267P | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR5I1 | c.631A>C p.I211L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PKHD1 | c.176A>T p.E59V | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RBP3 | c.826T>A p.F276I | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RELN | c.2191G>T p.G731C | Missense Mutation (SNP) | VAF 132/572 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RFFL | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA32 | c.1068-1G>T p.X356_splice | Splice Site (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- SREBF2 | c.2120A>G p.K707R | Missense Mutation (SNP) | VAF 237/295 reads (80%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- STPG3 | c.875C>T p.A292V (on ENST00000388931 / NM_001256699.1; = p.P287S on NM_001004353.3) | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TEX13C | c.2681T>A p.F894Y | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.928); called by muse, mutect2
- TNN | c.3872C>A p.T1291K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TTN | c.51547A>G p.K17183E (on ENST00000591111; = p.K9759E on NM_003319.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBQLN3 | c.1084G>T p.G362W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF671 | c.387T>C p.P129= | Splice Region (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- ZNF780B | c.320T>A p.I107K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ABCB1 | c.2298T>C p.S766= | Silent (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- ACACA | c.2391G>A p.G797= | Silent (SNP) | VAF 110/253 reads (43%) | called by muse, mutect2, varscan2
- ADARB2 | c.402C>T p.H134= | Silent (SNP) | VAF 110/224 reads (49%) | catalogued as rs766366626; called by muse, mutect2, varscan2
- AMPH | c.744G>A p.A248= | Silent (SNP) | VAF 64/224 reads (29%) | catalogued as rs188490881, COSV100340826; called by muse, mutect2, varscan2
- AOC1 | c.798G>A p.P266= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs370158924, COSV62867404; called by muse, mutect2, varscan2
- ATM | c.6258T>C p.Y2086= | Silent (SNP) | VAF 105/216 reads (49%) | called by muse, mutect2, varscan2
- ATP8A2 | c.2463C>T p.D821= | Silent (SNP) | VAF 60/158 reads (38%) | catalogued as rs759374071, COSV54947644; called by muse, mutect2, varscan2
- GPR78 | c.417C>T p.G139= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as rs774123662; called by muse, mutect2, varscan2
- HOXC13 | c.645G>A p.Q215= | Silent (SNP) | VAF 65/161 reads (40%) | called by muse, mutect2, varscan2
- KIT | c.792C>T p.H264= | Silent (SNP) | VAF 683/1111 reads (61%) | catalogued as rs753102574, COSV55397392; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRTO4 | c.108C>G p.T36= | Silent (SNP) | VAF 73/162 reads (45%) | called by muse, mutect2, varscan2
- MYF5 | c.462G>A p.S154= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs751777341, COSV57354383; called by muse, mutect2, varscan2
- OR2B2 | c.879G>A p.R293= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV57579113; called by muse, mutect2, varscan2
- PCDH9 | c.510C>T p.D170= | Silent (SNP) | VAF 19/129 reads (15%) | called by muse, mutect2, varscan2
- POSTN | c.2163T>A p.T721= | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- SPOPL | c.867C>T p.C289= | Silent (SNP) | VAF 62/141 reads (44%) | catalogued as rs746856558, COSV54511709; called by muse, mutect2, varscan2
- SYNM | c.450C>T p.R150= | Silent (SNP) | VAF 10/216 reads (5%) | catalogued as rs1555482517; called by muse, mutect2
- TCTN1 | c.360T>C p.C120= | Silent (SNP) | VAF 134/330 reads (41%) | catalogued as COSV66542665; called by muse, mutect2, varscan2
- ADRA1A | c.1270-7859C>A | Intron (SNP) | VAF 112/231 reads (48%) | called by muse, mutect2, varscan2
- AL603840.1 | n.770G>C | RNA (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- DOCK1 | c.1059-57G>A | Intron (SNP) | VAF 56/76 reads (74%) | catalogued as rs759971892; called by muse, mutect2, varscan2
- GOLGA8S | c.348+25G>A | Intron (SNP) | VAF 20/310 reads (6%) | catalogued as rs1330179118; called by muse, mutect2
- HEBP1 | c.398+3402C>A | Intron (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- SLIT3 | c.198-12178C>T | Intron (SNP) | VAF 26/64 reads (41%) | catalogued as rs764390519, COSV100265655; called by muse, mutect2, varscan2
- TNFRSF14 | c.304+628C>T | Intron (SNP) | VAF 60/165 reads (36%) | catalogued as rs748870499; called by muse, mutect2, varscan2
- TPRX2P | n.37G>A | RNA (SNP) | VAF 13/86 reads (15%) | catalogued as rs1305585639; called by mutect2, varscan2
- ZNF99 | c.*149C>T | 3'UTR (SNP) | VAF 61/158 reads (39%) | catalogued as rs778127782, COSV68056501; called by muse, mutect2, varscan2
